Somatic mutation profile of tumor specimen TCGA-FG-8189-01B (aliquot TCGA-FG-8189-01B-11D-A289-08) from TCGA case TCGA-FG-8189, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 33.9 years (12,384 days).
Specimen TCGA-FG-8189-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee01d8f0-f30b-4584-93dd-8bae20bdf2df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-8189-10A (Blood Derived Normal), aliquot TCGA-FG-8189-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea624129-c191-4987-94a1-a405749c347a

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.514A>T p.R172W | Missense Mutation (SNP) | VAF 8/92 reads (9%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1057519906, COSV57468942, COSV57468989, COSV57477941; ClinVar: likely pathogenic; called by muse, mutect2
- CTU2 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99966453; called by muse, mutect2
- FGF4 | c.506A>C p.Y169S | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51449430, COSV51450318; called by muse, mutect2
- ITPR3 | c.1181C>A p.T394N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65412004; called by muse, mutect2
- PRPS1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV65054511; called by muse, mutect2
- LRRC4C | c.786C>G p.A262= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV53431559; called by muse, mutect2
- MROH2B | c.234G>A p.E78= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV68187972; called by muse, mutect2
